CCDI case PBBXDM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/16fc0169-dd5d-42f4-a680-f49163f2074b

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.6 years (3,502 days).

Biospecimens (3 samples)
- Sample 0DJIKY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJIL9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJILU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
